CCDI case PBCCSS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/a53c68b3-f5f2-4c94-91d4-446efb8deb95

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 11.2 years (4,085 days).

Biospecimens (3 samples)
- Sample 0DQ2MX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ2N9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ2OU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
